Somatic mutation profile of tumor specimen MP2PRT-PATFLN-TMP1-A (aliquot MP2PRT-PATFLN-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATFLN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (870 days).
Specimen MP2PRT-PATFLN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1243a65-4989-4633-8f20-55cf6e050267.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFLN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFLN-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce50115f-3ae6-4f61-8f08-4f9310d14b62

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OR6M1 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 132/339 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100484029; called by muse, mutect2, varscan2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by muse, mutect2, varscan2
- LRRN1 | c.1952A>G p.Y651C | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- OR10H1 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 155/413 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DZIP3 | c.1473G>T p.P491= | Silent (SNP) | VAF 97/293 reads (33%) | catalogued as rs761465822, COSV64313196; called by muse, mutect2, varscan2
- ESRP1 | c.1029G>A p.V343= | Silent (SNP) | VAF 19/646 reads (3%) | called by muse, mutect2
